Somatic mutation profile of tumor specimen 1105251 (aliquot 7316UP-2923-1105251) from CPTAC case C1245129, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105251: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45a9d6a3-1c76-4bf8-94f8-e1f26b9021be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105282 (Blood Derived Normal), aliquot 7316UP-2923-1105282; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8783c8f0-e177-4cc6-b003-f7b438f40a51

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 4, Frame Shift Del 2, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 237/302 reads (78%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1567548929, COSV52662086, COSV52675732, COSV52773165, COSV52962390; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BIN3 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs73671219; called by muse, mutect2, varscan2
- CD1A | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 193/360 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs140989108, COSV56860759; called by muse, mutect2, varscan2
- CDH18 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs565236156, COSV56907812, COSV99932062; called by muse, mutect2, varscan2
- DOCK8 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 106/316 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs1227911560, COSV66634653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HHLA1 | c.1295C>A p.P432Q | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as rs1368020543; called by muse, mutect2, varscan2
- LARP1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 124/381 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs757070815, COSV60430890; called by muse, mutect2, varscan2
- MYO1G | c.2457G>C p.M819I | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.222); catalogued as rs767722811, COSV99348404; called by muse, mutect2, varscan2
- PCDHGA6 | c.1922G>A p.S641N | Missense Mutation (SNP) | VAF 172/481 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.044); catalogued as rs1265900699, COSV53948522; called by muse, mutect2, varscan2
- PROKR1 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 90/272 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs769294148; called by muse, mutect2, varscan2
- PTEN | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV64291337, COSV64303263; called by muse, mutect2, varscan2
- SAMD3 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1188118842, COSV60774329; called by muse, mutect2, varscan2
- SUSD2 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs750589882; called by muse, mutect2, varscan2
- VPS33B | c.1375G>A p.V459M | Missense Mutation (SNP) | VAF 147/383 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.287); catalogued as COSV60979239; called by muse, mutect2, varscan2
- BPTF | c.2618A>T p.K873M | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP54 | c.2804G>C p.W935S | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ECM2 | c.378C>G p.C126W | Missense Mutation (SNP) | VAF 104/299 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF5B | c.3398T>C p.V1133A | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, varscan2
- FASTKD3 | c.333_339del p.S112Kfs*3 | Frame Shift Del (DEL) | VAF 52/181 reads (29%) | called by mutect2, pindel, varscan2
- GLCCI1 | c.1438T>G p.S480A | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPR22 | c.974G>T p.C325F | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNQ3 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LIN52 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- LRRC37A3 | c.2297C>G p.S766C | Missense Mutation (SNP) | VAF 200/720 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- RB1 | c.1881del p.N627Kfs*16 | Frame Shift Del (DEL) | VAF 62/150 reads (41%) | called by mutect2, pindel, varscan2
- SNX13 | c.1042A>G p.I348V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- TACC2 | c.3875C>G p.A1292G | Missense Mutation (SNP) | VAF 83/128 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD6 | c.3350A>T p.E1117V | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- TTN | c.92867C>A p.P30956Q (on ENST00000591111; = p.P23532Q on NM_003319.4) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KCNA5 | c.642C>T p.R214= | Silent (SNP) | VAF 142/441 reads (32%) | catalogued as COSV99364284; called by muse, mutect2, varscan2
- PCDHAC2 | c.147A>G p.P49= | Silent (SNP) | VAF 100/303 reads (33%) | called by muse, mutect2, varscan2
- PLCH1 | c.4629C>T p.T1543= (on ENST00000340059 / NM_001130960.2; = p.T1535= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 108/327 reads (33%) | catalogued as rs374800898, COSV58185384; called by muse, mutect2, varscan2
- SUSD3 | c.537C>T p.H179= | Silent (SNP) | VAF 76/202 reads (38%) | catalogued as rs556738504; called by muse, mutect2, varscan2
- ADAM21P1 | n.1140C>T | RNA (SNP) | VAF 114/319 reads (36%) | catalogued as rs755338109; called by muse, mutect2, varscan2
- NGDN | c.72+17C>G | Intron (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- RTEL1 | c.958+23C>T | Intron (SNP) | VAF 60/192 reads (31%) | called by muse, mutect2
